Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4807, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4807-01A (Primary Tumor).

[page 1 of 2]
TCGA-BP-4807

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

2 [REDACTED] with right renal mass.

Specimens Submitted:

1: Kidney, right; partial nephrectomy

DIAGNOSIS:

1. Kidney, right; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 1.9 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not applicable

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "right renal tumor, stitch marks deep margin." It consists of a 4.0 x 2.1x 2.0 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a well circumscribed golden yellow orange tumor, measuring 1.9 x 1.8 x 1.5 cm. The clearance from the resection margin is 0.2 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections uninvolved parenchyma

Summary of Sections:

Part 1: Kidney, right; partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
1	M	1
1	RS	1
1	T	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RIGHT RENAL TUMOR (REDACTED). RENAL CORTICAL EPITHELIAL TUMOR. MARGIN IS CLOSE (APPROXIMATELY 0.2 CM) BUT CLEAR. (REDACTED)

PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 068242bb-521e-4b48-9b35-8b7eeaca35a6 (TCGA-BP-4807.E90EBECF-B60A-42A1-9399-1A429093BD29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).